Somatic mutation profile of cancer-model specimen HCM-CSHL-1266-C20-85M (3D Organoid; aliquot HCM-CSHL-1266-C20-85M-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 34.7 years (12,684 days).
Specimen HCM-CSHL-1266-C20-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c8a9f00-256b-4594-8d6f-ae23f3d000b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1266-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-1266-C20-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2688eb7a-6743-4d13-abb6-71de78f4f99b

The open-access MAF lists 135 somatic variants for this specimen: 102 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Nonsense Mutation 9, Translation Start Site 2, Frame Shift Del 2, Frame Shift Ins 2, Splice Region 1, 3'Flank 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 613/614 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AL592490.1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 196/666 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV69425032; called by muse, mutect2, varscan2
- ARHGEF28 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 78/158 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1298080364, COSV104383102; called by muse, varscan2
- ATF5 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs531308133; called by muse, mutect2, varscan2
- CACNA1B | c.4376C>T p.S1459L | Missense Mutation (SNP) | VAF 142/552 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs775488955, COSV53149897; called by muse, mutect2, varscan2
- CLCN4 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66466160; called by muse, mutect2, varscan2
- COL5A2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 95/237 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs983377642, COSV66410763; called by muse, mutect2, varscan2
- CSMD3 | c.2876C>A p.S959* (on ENST00000297405 / NM_001363185.1; = p.S855* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 136/468 reads (29%) | catalogued as COSV52287772; called by muse, mutect2, varscan2
- DUSP23 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 91/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192795373; called by muse, mutect2, varscan2
- EEF1A2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 230/977 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1325353717, COSV53207183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENTPD4 | c.1644C>A p.F548L | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV62268138; called by muse, mutect2, varscan2
- FAT3 | c.8505A>T p.Q2835H | Missense Mutation (SNP) | VAF 204/363 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969150; called by muse, mutect2, varscan2
- GABRA5 | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 115/292 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475409; called by muse, mutect2, varscan2
- GALNT9 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 340/340 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1486896844; called by muse, mutect2, varscan2
- GPR158 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs1047586610, COSV66267663; called by muse, mutect2, varscan2
- HECW1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 265/672 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.37); catalogued as rs754513729, COSV67825760, COSV67831887; called by muse, mutect2, varscan2
- IGHG3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 135/435 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs745813727; called by muse, mutect2, varscan2
- LATS1 | c.800C>A p.S267* | Nonsense Mutation (SNP) | VAF 224/427 reads (52%) | catalogued as COSV53588519; called by muse, mutect2, varscan2
- LLGL1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 261/454 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57500849; called by muse, mutect2, varscan2
- LRIF1 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 423/424 reads (100%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs775682328; called by muse, mutect2, varscan2
- LRRC69 | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1428918343; called by muse, mutect2, varscan2
- MASP1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 153/263 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs760110023; called by muse, mutect2, varscan2
- MFAP3L | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs200622205, COSV64372678; called by muse, mutect2, varscan2
- MUC16 | c.11376G>A p.M3792I | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs754905495; called by muse, mutect2, varscan2
- OR10C1 | c.534C>A p.F178L (on ENST00000622521; = p.F176L on NM_013941.3) | Missense Mutation (SNP) | VAF 368/756 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1215726941, COSV65822546; called by muse, mutect2, varscan2
- PC | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67369447; called by muse, mutect2, varscan2
- PCDHGA10 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 345/743 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs746539261, COSV99540054; called by muse, mutect2, varscan2
- PDPR | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 92/396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs957183542; called by muse, mutect2, varscan2
- PPIL2 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769760032; called by muse, mutect2, varscan2
- PPP4R4 | c.2611T>A p.S871T | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.969); catalogued as rs750925625; called by mutect2, varscan2
- RBMXL3 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 157/474 reads (33%) | catalogued as rs1373914939, COSV100407349; called by muse, mutect2, varscan2
- ROBO2 | c.1482T>G p.S494R | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs13060040; called by muse, mutect2, varscan2
- RYR3 | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 227/483 reads (47%) | catalogued as rs1297136189; called by muse, mutect2, varscan2
- SCN1A | c.5822C>T p.T1941M (on ENST00000303395 / NM_001202435.3; = p.T1930M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/210 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs756845310, COSV57660387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC62 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 128/299 reads (43%) | catalogued as rs141360935; called by muse, mutect2, varscan2
- SLC22A2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 589/589 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1314319598, COSV65266636; called by muse, mutect2, varscan2
- SLC22A8 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs769079351; called by muse, mutect2, varscan2
- SLC24A5 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 193/418 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1312635224, COSV58316551; called by muse, mutect2, varscan2
- SLITRK5 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 191/943 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs144076922, COSV100280998; called by muse, mutect2, varscan2
- SPAG5 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs374794062; called by muse, mutect2, varscan2
- SPDYE4 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751622086, COSV100171288; called by muse, mutect2, varscan2
- SRRM2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs745979288; called by muse, mutect2, varscan2
- SYNE1 | c.10730A>C p.Q3577P (on ENST00000367255 / NM_182961.4; = p.Q3584P on NM_033071.3) | Missense Mutation (SNP) | VAF 206/394 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs757925072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCAF1 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 109/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775955914; called by muse, mutect2, varscan2
- TIAM1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970048985, COSV99732887; called by muse, mutect2, varscan2
- TMEM200A | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775367537; called by muse, mutect2, varscan2
- ZBTB43 | c.662A>C p.D221A | Missense Mutation (SNP) | VAF 388/541 reads (72%) | SIFT tolerated (0.3); PolyPhen benign (0.206); catalogued as rs771306645, COSV65094936; called by muse, varscan2
- ZC3H3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 661/1028 reads (64%) | catalogued as rs764083420; called by muse, mutect2, varscan2
- ZC3H4 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 185/278 reads (67%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.723); catalogued as rs1369711181; called by muse, mutect2, varscan2
- ZFYVE9 | c.3113C>G p.S1038C | Missense Mutation (SNP) | VAF 178/333 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs192873630; called by muse, mutect2, varscan2
- ZNF84 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 345/346 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs944613069; called by muse, mutect2, varscan2
- ABHD14B | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AJUBA | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 432/669 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- AL031777.2 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANXA8 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 365/586 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.4055_4064delinsAT p.V1352Dfs*20 | Frame Shift Del (DEL) | VAF 240/242 reads (99%) | called by pindel, varscan2*
- AQR | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL14EP | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ASTN1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC178 | c.2522A>T p.Q841L (on ENST00000383096 / NM_001105528.3; = p.Q803L on NM_198995.3) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC88B | c.3469_3470delinsT p.E1157Cfs*63 | Frame Shift Del (DEL) | VAF 147/583 reads (25%) | called by pindel, varscan2*
- CDC7 | c.298A>T p.R100* | Nonsense Mutation (SNP) | VAF 142/304 reads (47%) | called by muse, mutect2, varscan2
- COL18A1 | c.4550C>T p.P1517L (on ENST00000359759 / NM_130444.3; = p.P1282L on NM_030582.4) | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CPN2 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 145/404 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCAF1 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DPM1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L5 | c.1421T>G p.M474R | Missense Mutation (SNP) | VAF 205/454 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- FAM76A | c.840C>A p.A280= | Splice Region (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- FUT4 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 310/609 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- GAN | c.13A>T p.S5C | Missense Mutation (SNP) | VAF 83/382 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYATL3 | c.753_755del p.D252del | In Frame Del (DEL) | VAF 217/440 reads (49%) | called by mutect2, pindel, varscan2
- GRID2IP | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 204/917 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- GTF2I | c.1127C>T p.A376V (on ENST00000573035 / NM_032999.4; = p.A335V on NM_001518.5) | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HDAC3 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HOXA7 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 206/559 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IGHV1-46 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IKZF2 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 179/263 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS4 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 260/404 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, varscan2
- ITIH5 | c.1115A>T p.D372V | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ITIH5 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LAMC3 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 337/500 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LRRFIP1 | c.693A>T p.Q231H (on ENST00000392000 / NM_001137552.2; = p.Q207H on NM_004735.4) | Missense Mutation (SNP) | VAF 119/407 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ODF2 | c.2485G>A p.A829T (on ENST00000434106 / NM_153433.2; = p.A805T on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C12 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.5669C>A p.A1890E | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PITPNM2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, varscan2
- PNISR | c.1619C>G p.S540* | Nonsense Mutation (SNP) | VAF 151/314 reads (48%) | called by muse, mutect2, varscan2
- POGLUT1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PTBP3 | c.1069A>C p.N357H | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SPAG1 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 137/818 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STEAP2 | c.1275A>C p.R425S | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TAF1A | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFPI | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TP53BP1 | c.1670C>G p.S557C | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TSHZ3 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 336/538 reads (62%) | called by muse, mutect2, varscan2
- VWA5A | c.2119A>T p.S707C | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ZBED4 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 201/420 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, varscan2
- ZNF831 | c.2825T>A p.L942H | Missense Mutation (SNP) | VAF 140/1154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF84 | c.1701dup p.E568Rfs*5 | Frame Shift Ins (INS) | VAF 110/319 reads (34%) | called by mutect2, varscan2
- ZNF84 | c.1707dup p.P570Tfs*3 | Frame Shift Ins (INS) | VAF 115/468 reads (25%) | called by mutect2*, pindel, varscan2*
- ZNF888 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANK3 | c.3009C>T p.H1003= (on ENST00000280772 / NM_001320874.2; = p.H137= on NM_001149.3) | Silent (SNP) | VAF 302/302 reads (100%) | catalogued as rs147312170; called by muse, varscan2
- AP2A2 | c.534G>A p.T178= | Silent (SNP) | VAF 245/246 reads (100%) | catalogued as rs757988092; called by muse, mutect2, varscan2
- ATP13A4 | c.3549T>G p.S1183= | Silent (SNP) | VAF 79/224 reads (35%) | catalogued as COSV61321448; called by muse, mutect2, varscan2
- ATP8A2 | c.3217T>C p.L1073= | Silent (SNP) | VAF 59/355 reads (17%) | catalogued as rs1163479170; called by muse, mutect2, varscan2
- BGN | c.615C>T p.F205= | Silent (SNP) | VAF 109/351 reads (31%) | catalogued as rs935930397, COSV59036001; called by muse, mutect2, varscan2
- CCDC178 | c.6T>C p.T2= | Silent (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- CHSY3 | c.126C>T p.S42= | Silent (SNP) | VAF 468/469 reads (100%) | called by muse, mutect2, varscan2
- DAGLB | c.1479G>T p.G493= | Silent (SNP) | VAF 164/452 reads (36%) | called by muse, mutect2, varscan2
- ELF1 | c.573G>A p.T191= | Silent (SNP) | VAF 103/402 reads (26%) | catalogued as rs138849972; called by muse, mutect2, varscan2
- ERI2 | c.273A>G p.E91= | Silent (SNP) | VAF 96/242 reads (40%) | called by muse, mutect2, varscan2
- FAT3 | c.9411C>T p.N3137= | Silent (SNP) | VAF 75/320 reads (23%) | called by muse, mutect2, varscan2
- GABBR1 | c.504C>T p.R168= | Silent (SNP) | VAF 357/838 reads (43%) | catalogued as rs1049475813; called by muse, mutect2, varscan2
- GAL3ST4 | c.1323T>C p.S441= | Silent (SNP) | VAF 92/533 reads (17%) | called by muse, mutect2, varscan2
- HEATR1 | c.1659G>T p.T553= | Silent (SNP) | VAF 91/202 reads (45%) | catalogued as rs775414720, COSV63983406; called by muse, mutect2, varscan2
- KCNT1 | c.2634G>A p.A878= (on ENST00000488444; = p.A897= on NM_020822.3) | Silent (SNP) | VAF 233/328 reads (71%) | catalogued as rs142642528; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- KDM6A | c.2709A>C p.L903= | Silent (SNP) | VAF 59/60 reads (98%) | called by muse, mutect2, varscan2
- KLHL11 | c.1995C>T p.Y665= | Silent (SNP) | VAF 89/286 reads (31%) | called by muse, mutect2, varscan2
- LLGL1 | c.558A>T p.P186= | Silent (SNP) | VAF 260/456 reads (57%) | called by muse, mutect2, varscan2
- MAP7D3 | c.2406A>T p.P802= | Silent (SNP) | VAF 104/348 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.20460A>G p.L6820= | Silent (SNP) | VAF 163/256 reads (64%) | called by muse, mutect2, varscan2
- NAALAD2 | c.573T>C p.V191= | Silent (SNP) | VAF 93/183 reads (51%) | called by muse, mutect2, varscan2
- NPAP1 | c.75C>T p.P25= | Silent (SNP) | VAF 305/618 reads (49%) | catalogued as rs776835685, COSV61508007; called by muse, mutect2, varscan2
- NUSAP1 | c.414C>T p.D138= | Silent (SNP) | VAF 173/375 reads (46%) | catalogued as rs747528263; called by muse, mutect2, varscan2
- PCDH11X | c.39G>A p.L13= | Silent (SNP) | VAF 307/307 reads (100%) | called by muse, mutect2, varscan2
- RTL3 | c.1398G>T p.L466= | Silent (SNP) | VAF 94/296 reads (32%) | called by muse, mutect2, varscan2
- SGSM1 | c.2649G>A p.A883= (on ENST00000400359 / NM_001039948.4; = p.A822= on NM_133454.3) | Silent (SNP) | VAF 242/478 reads (51%) | catalogued as rs770834809; called by muse, varscan2
- SHANK1 | c.93C>T p.D31= | Silent (SNP) | VAF 302/610 reads (50%) | catalogued as rs764205732, COSV99520023; called by muse, mutect2, varscan2
- TNRC6C | c.2148G>A p.P716= | Silent (SNP) | VAF 199/397 reads (50%) | catalogued as rs768647250; called by muse, mutect2, varscan2
- TRIM72 | c.1311G>A p.P437= | Silent (SNP) | VAF 206/450 reads (46%) | catalogued as rs1224431203; called by muse, mutect2, varscan2
- TTN | c.21396A>G p.Q7132= (on ENST00000591111; = p.Q6205= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 140/229 reads (61%) | catalogued as COSV60190155; called by muse, mutect2, varscan2
- UBC | c.177C>T p.Y59= | Silent (SNP) | VAF 127/466 reads (27%) | catalogued as rs11537757; called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996243 G>A | 5'Flank (SNP) | VAF 95/331 reads (29%) | catalogued as rs1049331924; called by muse, mutect2, varscan2
- PTPRU | chr1:29325739 C>T | 3'Flank (SNP) | VAF 332/657 reads (51%) | catalogued as rs765826238; called by muse, mutect2, varscan2
